Somatic mutation profile of cancer-model specimen HCM-BROD-1129-C56-85B (3D Organoid, passage 7; aliquot HCM-BROD-1129-C56-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-1129-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 61.4 years (22,421 days).
Specimen HCM-BROD-1129-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffe2515d-e61c-4401-8d16-d30334dc3ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1129-C56-10A (Blood Derived Normal), aliquot HCM-BROD-1129-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61c51c9d-dd28-4554-9944-722ece84de1f

The open-access MAF lists 115 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 24, Nonsense Mutation 8, Frame Shift Del 6, Splice Region 2, Intron 2, In Frame Del 1, 3'Flank 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 147/344 reads (43%) | catalogued as rs80357215, CM062467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 141/492 reads (29%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMC2 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs747981959, COSV100933429; called by muse, mutect2, varscan2
- CACNA1C | c.3568G>A p.V1190M | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1048241141; called by muse, mutect2, varscan2
- CCDC88C | c.4991C>T p.S1664F | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753949290, COSV57798114; called by muse, mutect2
- CHRM2 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 99/461 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57769127, COSV57775493; called by muse, mutect2, varscan2
- CSF3R | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 110/528 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs112400536; called by muse, mutect2, varscan2
- CSMD3 | c.8957C>A p.P2986H (on ENST00000297405 / NM_001363185.1; = p.P2817H on NM_052900.3) | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs766713536, COSV52260967; called by muse, mutect2, varscan2
- DCAF4 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 87/390 reads (22%) | catalogued as COSV62320700; called by muse, mutect2, varscan2
- FLNC | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs746183882; called by muse, mutect2, varscan2
- HEG1 | c.2423C>G p.A808G | Missense Mutation (SNP) | VAF 87/481 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100229979; called by muse, mutect2, varscan2
- HTR2A | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV66326919; called by muse, mutect2, varscan2
- ITGB5 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 88/523 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as rs1441790838; called by muse, mutect2, varscan2
- KDM3B | c.4414C>T p.R1472* | Nonsense Mutation (SNP) | VAF 43/219 reads (20%) | catalogued as rs1561796122, COSV100069409, COSV58693606; called by muse, mutect2, varscan2
- MACF1 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 152/421 reads (36%) | catalogued as rs140873304; called by muse, mutect2, varscan2
- MORC4 | c.2172del p.V725Lfs*39 | Frame Shift Del (DEL) | VAF 131/692 reads (19%) | catalogued as COSV55245309; called by mutect2, pindel, varscan2
- MPV17L | c.457G>A p.A153T (on ENST00000396385 / NM_001128423.2; = p.R129H on NM_173803.4) | Missense Mutation (SNP) | VAF 150/630 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757414085, COSV55009252; called by muse, mutect2, varscan2
- MUC6 | c.7232C>T p.P2411L | Missense Mutation (SNP) | VAF 195/847 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs374718574, COSV104407690; called by muse, mutect2, varscan2
- NLRP10 | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 161/660 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as COSV60779955, COSV60782844; called by muse, mutect2, varscan2
- NLRP6 | c.1763G>A p.G588E | Missense Mutation (SNP) | VAF 127/496 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.026); catalogued as rs1389319246; called by muse, varscan2
- OR5M8 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100510621; called by muse, mutect2
- PCLO | c.4498G>T p.V1500F | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as rs372304800; called by muse, mutect2, varscan2
- RABGGTA | c.1236G>A p.K412= | Splice Region (SNP) | VAF 59/305 reads (19%) | catalogued as rs1259855644; called by muse, mutect2, varscan2
- SLC6A16 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs534129369; called by muse, mutect2, varscan2
- SLC9A4 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 79/454 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766908354, COSV54828977; called by muse, mutect2, varscan2
- SORCS1 | c.2819G>A p.S940N | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs1032275681; called by muse, mutect2, varscan2
- TBC1D8B | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 58/288 reads (20%) | catalogued as rs745935519, COSV52175615; called by muse, varscan2
- TRIM8 | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 194/868 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774633423; called by muse, mutect2, varscan2
- ADAMTS13 | c.3860G>T p.G1287V | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AKAP17A | c.1546_1559del p.V516Pfs*32 | Frame Shift Del (DEL) | VAF 167/866 reads (19%) | called by mutect2, pindel, varscan2
- ARSK | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BRCA1 | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- C10orf71 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CAPN9 | c.789G>A p.Q263= | Splice Region (SNP) | VAF 57/328 reads (17%) | called by muse, mutect2, varscan2
- CD207 | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 91/443 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDRT1 | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- CNOT11 | c.1350_1386del p.L451Kfs*10 | Frame Shift Del (DEL) | VAF 42/274 reads (15%) | called by mutect2, pindel
- CST11 | c.280_284delinsC p.C94Qfs*37 | Frame Shift Del (DEL) | VAF 64/312 reads (21%) | called by pindel, varscan2*
- CUZD1 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- DIAPH2 | c.2909A>T p.K970M | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJB11 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- FAM78A | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 122/514 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FAT4 | c.10904T>C p.L3635S | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.9688G>A p.E3230K | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSTL3 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 110/345 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRP | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 94/269 reads (35%) | called by muse, mutect2, varscan2
- GAL | c.93A>C p.K31N | Missense Mutation (SNP) | VAF 241/489 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GHDC | c.909del p.Q304Sfs*50 | Frame Shift Del (DEL) | VAF 74/426 reads (17%) | called by mutect2, pindel*, varscan2
- GRIA3 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 143/635 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GRM3 | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 104/434 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- HSF1 | c.50_68del p.A17Gfs*4 | Frame Shift Del (DEL) | VAF 72/860 reads (8%) | called by mutect2, pindel
- IGDCC3 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KBTBD11 | c.1558A>G p.S520G | Missense Mutation (SNP) | VAF 191/1253 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2012 | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.1); called by mutect2, varscan2
- KRT36 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 270/541 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KRTAP11-1 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- LRP2 | c.7284T>A p.S2428R | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC37B | c.2030T>G p.L677R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MORN3 | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 138/529 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MYCBPAP | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 193/423 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NCCRP1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 112/508 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NCOR1 | c.6996C>G p.S2332R | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NOTCH3 | c.4736G>C p.G1579A | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- OR10A7 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- OR13C8 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3C2G | c.2818G>T p.A940S (on ENST00000676171; = p.A899S on NM_004570.5) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIN4 | c.221G>A p.G74D (on ENST00000664196; = p.G49D on NM_006223.4) | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, varscan2
- PLEKHG1 | c.2468_2491del p.P823_K830del | In Frame Del (DEL) | VAF 68/334 reads (20%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 181/775 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- POLN | c.2139G>T p.Q713H | Missense Mutation (SNP) | VAF 98/550 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PPM1G | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 92/490 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PRMT8 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RABL2B | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIF1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RNF148 | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SART1 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 113/395 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SBNO2 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 124/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA4C | c.477T>A p.C159* | Nonsense Mutation (SNP) | VAF 94/482 reads (20%) | called by muse, mutect2, varscan2
- SSTR5 | c.735G>C p.K245N | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 11/249 reads (4%) | PolyPhen benign (0.389); called by muse, mutect2
- TMPRSS15 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE4A | c.1954G>A p.D652N (on ENST00000252108 / NM_001204077.2; = p.D659N on NM_004788.4) | Missense Mutation (SNP) | VAF 78/494 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UBXN7 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 116/682 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- USH2A | c.13584C>A p.S4528R | Missense Mutation (SNP) | VAF 115/495 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WDR62 | c.1840T>A p.S614T | Missense Mutation (SNP) | VAF 106/388 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADARB2 | c.231C>T p.N77= | Silent (SNP) | VAF 119/575 reads (21%) | called by muse, mutect2, varscan2
- AGXT | c.39C>T p.A13= | Silent (SNP) | VAF 146/640 reads (23%) | catalogued as rs530836808; called by muse, mutect2
- ALDH1B1 | c.708C>T p.N236= | Silent (SNP) | VAF 107/461 reads (23%) | catalogued as rs779188273; called by muse, mutect2, varscan2
- ATR | c.6777C>T p.L2259= | Silent (SNP) | VAF 84/341 reads (25%) | called by muse, mutect2, varscan2
- BAZ1A | c.4104A>G p.P1368= | Silent (SNP) | VAF 81/369 reads (22%) | called by muse, mutect2, varscan2
- CCDC142 | c.399C>T p.G133= | Silent (SNP) | VAF 159/686 reads (23%) | called by muse, mutect2, varscan2
- COX6A1 | c.21C>G p.S7= | Silent (SNP) | VAF 109/407 reads (27%) | catalogued as rs751396273, COSV57569347; called by muse, mutect2, varscan2
- F9 | c.642C>T p.I214= | Silent (SNP) | VAF 140/718 reads (19%) | called by muse, mutect2
- FFAR2 | c.255G>C p.T85= | Silent (SNP) | VAF 171/679 reads (25%) | catalogued as COSV55833009; called by muse, mutect2, varscan2
- LMTK2 | c.2556C>T p.D852= | Silent (SNP) | VAF 208/565 reads (37%) | catalogued as rs753563271; called by muse, mutect2, varscan2
- METTL26 | c.117C>G p.G39= | Silent (SNP) | VAF 180/607 reads (30%) | called by muse, mutect2, varscan2
- MOV10L1 | c.3135C>A p.R1045= | Silent (SNP) | VAF 167/478 reads (35%) | catalogued as rs774761866; called by muse, mutect2, varscan2
- MTCL1 | c.3879C>T p.N1293= (on ENST00000306329 / NM_001378206.1; = p.N974= on NM_015210.4) | Silent (SNP) | VAF 119/521 reads (23%) | catalogued as rs142108234; called by muse, mutect2, varscan2
- MYNN | c.1056T>C p.H352= | Silent (SNP) | VAF 237/478 reads (50%) | called by muse, mutect2, varscan2
- MYOM2 | c.777G>A p.V259= | Silent (SNP) | VAF 94/800 reads (12%) | called by muse, mutect2, varscan2
- NOTUM | c.603C>T p.A201= | Silent (SNP) | VAF 102/442 reads (23%) | called by muse, mutect2, varscan2
- OBP2A | c.366G>T p.L122= | Silent (SNP) | VAF 70/350 reads (20%) | called by muse, mutect2, varscan2
- PCYT2 | c.819G>A p.L273= | Silent (SNP) | VAF 110/482 reads (23%) | called by muse, mutect2, varscan2
- PFKL | c.864C>G p.G288= | Silent (SNP) | VAF 105/547 reads (19%) | called by muse, mutect2, varscan2
- PRDM10 | c.2154G>T p.T718= | Silent (SNP) | VAF 434/714 reads (61%) | catalogued as COSV58804771; called by muse, mutect2, varscan2
- PSD | c.1776G>C p.G592= | Silent (SNP) | VAF 76/343 reads (22%) | catalogued as COSV50047180; called by muse, mutect2, varscan2
- RBL1 | c.1710C>T p.H570= | Silent (SNP) | VAF 102/431 reads (24%) | catalogued as rs751661963, COSV60332645; called by muse, mutect2, varscan2
- SLC9C1 | c.324T>A p.L108= | Silent (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- ULK1 | c.417G>A p.L139= | Silent (SNP) | VAF 145/723 reads (20%) | catalogued as rs756833009; called by muse, mutect2, varscan2
- C11orf52 | chr11:111929908 T>C | 3'Flank (SNP) | VAF 88/405 reads (22%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2716_2044-2710delinsGT | Intron (DEL) | VAF 82/404 reads (20%) | called by pindel, varscan2*
- LINC02694 | n.33A>T | RNA (SNP) | VAF 84/301 reads (28%) | catalogued as rs745525527, COSV59558669; called by muse, mutect2, varscan2
- MAP4 | c.1999+3322_1999+3341del | Intron (DEL) | VAF 39/194 reads (20%) | called by mutect2, pindel, varscan2
- NUTM1 | c.-63G>C | 5'UTR (SNP) | VAF 168/476 reads (35%) | called by muse, mutect2, varscan2
- WNK1 | c.*2585_*2597del | 3'UTR (DEL) | VAF 66/394 reads (17%) | called by mutect2, pindel, varscan2
